Gene-level copy-number profile of tumor specimen RC-B5D0-TBR1-A from RC case RC-B5D0, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Dead; Primary diagnosis: Peripheral T-cell lymphoma, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 80.2 years (29,284 days).
Specimen RC-B5D0-TBR1-A: Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dc15c82c-d0a3-47d2-9c81-2c502ec14f44.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator RC-B5D0-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,724 have no estimate.
https://portal.gdc.cancer.gov/files/27e1c902-6820-4fe3-bfbe-0becce7df78d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 155; copy number 1: 4,297; copy number 2: 54,349; copy number 3: 98.

Homozygous deletions (total copy number 0; autosomes only): 155 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:188,155,839–192,011,260, 30 genes: RN7SKP156, AL596211.1, AL592447.1, AL929288.1, AL929288.2, RPS3AP9, AL691515.1, AL691515.2, LINC01035, CLPTM1LP1, GAPDHP75, RNA5SP73, LINC01701, AL591504.1, AL591504.2, AL359976.1, BRINP3, AL354771.1, LINC01351, AL391645.1, LINC01720, AL139135.1, AL139135.2, AL138927.1, HNRNPA1P46, AL713866.1, AL713866.2, LINC01680, LINC02770, AL359081.1.
- chr7:38,256,337–38,296,233, 7 genes (within-gene range 0–2): TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB.
- chr14:21,829,539–22,552,156, 118 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,441. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
